Gene-level copy-number profile of tumor specimen TCGA-DM-A288-01A from TCGA case TCGA-DM-A288, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.7 years (25,084 days).
Specimen TCGA-DM-A288-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.fec5a2f9-0423-430e-a988-5f46d6d8b117.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A288-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe3cf5bd-112e-4cc6-9974-ebab474cdd8e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 1,153; copy number 2: 12,625; copy number 3: 30,009; copy number 4: 4,869; copy number 5: 5,430; copy number 6: 3,747; copy number 7: 1,882.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A288-01A-11D-A16U-01): tumor purity 0.83, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:99,489,559–109,688,329, 94 genes (broad region; genes not listed).
- chr5:109,699,500–109,699,834, 1 gene: RN7SKP230.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,882 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:118,757,518–170,738,536, 816 genes, copy number 7 (broad region; genes not listed).
- chr7:70,972–57,770,946, 1,066 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
